Somatic mutation profile of tumor specimen TCGA-BS-A0TD-01A (aliquot TCGA-BS-A0TD-01A-11D-A10B-09) from TCGA case TCGA-BS-A0TD, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Corpus uteri; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 65.6 years (23,950 days).
Specimen TCGA-BS-A0TD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05e8d799-f2f6-4009-b3fc-7b7ee971438a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BS-A0TD-10A (Blood Derived Normal), aliquot TCGA-BS-A0TD-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bddfa703-115f-41cf-9712-4b4b59a0f7be

The open-access MAF lists 42 somatic variants for this specimen: 29 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 10, Frame Shift Del 3, Splice Site 2, In Frame Del 2, Intron 1, RNA 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 24/75 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1727_1729del p.T576del (on ENST00000521381 / NM_181523.3; = p.T306del on NM_181504.4) | In Frame Del (DEL) | VAF 35/145 reads (24%) | hotspot (GDC flag); catalogued as rs1057519842; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.987_990del p.N329Kfs*14 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | catalogued as rs587782304; ClinVar: pathogenic; called by pindel, varscan2
- ADAMTS20 | c.2437C>T p.R813* | Nonsense Mutation (SNP) | VAF 19/264 reads (7%) | catalogued as COSV67132463; called by muse, mutect2
- AQP9 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as rs367676440, COSV54968868; called by muse, mutect2, varscan2
- ASAP1 | c.1306G>T p.D436Y | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63049043; called by muse, mutect2, varscan2
- BIRC3 | c.1366C>A p.Q456K | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.285); catalogued as COSV54817176, COSV54820188; called by muse, mutect2, varscan2
- CDC123 | c.440+1G>A p.X147_splice | Splice Site (SNP) | VAF 27/85 reads (32%) | catalogued as rs771244677, COSV55397894; called by muse, mutect2, varscan2
- EPHA3 | c.1812C>A p.D604E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.857); catalogued as COSV60708197; called by muse, mutect2, varscan2
- JCAD | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1035729518, COSV64759918; called by muse, mutect2, varscan2
- LVRN | c.1759G>A p.V587I | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs367939302, COSV63497362; called by muse, mutect2, varscan2
- NAXD | c.326C>G p.A109G | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as COSV59394717; called by muse, mutect2
- NRP1 | c.2751G>C p.Q917H | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as rs1158664603, COSV55168132; called by muse, mutect2, varscan2
- PADI3 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs148271347; called by muse, mutect2
- PASD1 | c.1670A>G p.E557G | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV64855526; called by muse, mutect2, varscan2
- PASK | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs757893760, COSV52153592; called by muse, mutect2, varscan2
- PSMC6 | c.659A>G p.K220R (on ENST00000612399; = p.K206R on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/229 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV71628827; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 22/69 reads (32%) | catalogued as rs146650273; called by pindel, varscan2
- PTPN7 | c.989+1G>A p.X330_splice (on ENST00000495688; = p.X369_splice on NM_002832.4 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 9/24 reads (38%) | catalogued as COSV58313044; called by muse, mutect2, varscan2
- RANBP6 | c.2513A>G p.D838G | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV52389637; called by muse, mutect2, varscan2
- RASA1 | c.2054C>G p.A685G | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.07); catalogued as COSV57196014; called by muse, mutect2, varscan2
- RNF144A | c.470C>G p.P157R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.027); catalogued as COSV57982742; called by muse, mutect2
- SERTAD1 | c.629T>C p.L210P | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV63596224; called by muse, mutect2, varscan2
- SGCG | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54561461; called by muse, mutect2, varscan2
- SLC38A7 | c.23A>G p.N8S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs370515708; called by muse, mutect2, varscan2
- VGLL4 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs866158596, COSV56077484; called by muse, mutect2, varscan2
- NPAP1 | c.1432_1449del p.N478_S483del | In Frame Del (DEL) | VAF 34/100 reads (34%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1378del p.S460Vfs*20 (on ENST00000521381 / NM_181523.3; = p.S190Vfs*20 on NM_181504.4) | Frame Shift Del (DEL) | VAF 54/223 reads (24%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.6465G>A p.P2155= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs777321727, COSV64137475; called by muse, mutect2, varscan2
- FNDC1 | c.1851G>A p.S617= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs1439876281, COSV51939027; called by muse, mutect2
- MCF2 | c.279C>T p.I93= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV58485485; called by muse, mutect2, varscan2
- MCM5 | c.1155A>T p.T385= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV53346474; called by muse, mutect2, varscan2
- MUC5B | c.2985C>T p.I995= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs772897397, COSV71592226; called by muse, mutect2, varscan2
- PCDHA11 | c.460C>T p.L154= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV56506870; called by muse, mutect2, varscan2
- PCDHGA3 | c.1107C>T p.I369= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as rs1446144250, COSV53951851; called by muse, mutect2, varscan2
- PFAS | c.444G>A p.R148= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV58980689; called by muse, mutect2, varscan2
- PIK3C2A | c.4335A>G p.V1445= | Silent (SNP) | VAF 47/136 reads (35%) | catalogued as COSV56403244; called by muse, mutect2, varscan2
- RAB28 | c.300C>T p.S100= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV56539756; called by muse, mutect2, varscan2
- DCHS2 | n.210G>A | RNA (SNP) | VAF 16/49 reads (33%) | catalogued as rs376998218; called by muse, mutect2, varscan2
- P4HTM | c.1074-11del | Intron (DEL) | VAF 5/30 reads (17%) | catalogued as rs760453324, COSV59086098; called by mutect2, pindel
- RN7SL262P | chrX:49157341 C>T | 3'Flank (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
